Surgical pathology report (de-identified scan), TCGA case TCGA-DD-AADD, project TCGA-LIHC (Liver Hepatocellular Carcinoma), tissue source site Mayo Clinic - Rochester, specimen TCGA-DD-AADD-01A (Primary Tumor).

[page 1 of 2]
ICD-O-3

Carcinoma, hepatocellular NOS 8170/3

Site: Liver NOS C22.0

Q2 5/19/14

CLINICAL DIAGNOSIS: HCC

Specimen : liver

Gross Photo :

GROSS:

Specimen status: Fresh

Operation: Right posterior sectionectomy

Organ:

Liver, right posterior (15.0 x 10.5 x 8.5 cm, 780.0 gm), (16.0 x 5.0 x 3.5 cm, 75.5 gm)

Adrenal gland (5.5 x 2.5 x 0.3 cm)

Gallbladder (8.5 cm in length, 4.5 cm in diameter)

Lesion: Hepatic mass

Size: 7.5 x 6.6 x 5.1 cm

Cut surface: Encapsulated, pale tan and nodular mass with central necrosis

Gross type: Multinodular confluent

Extent: Confined to the capsule

Resection margin: Not involved, grossly (safety margin: 1.5 cm)

Remaining parenchyme: Unremarkable

[Gallbladder]

Serosal surface: Yellowish pink and smooth

Mucosal surface: Dark green and velvety, no mural nodule

Representative sections are submitted.

Gross photo: Present

Blocks

T1-6, mass of liver x 6

RM, tumor with resection margin x 1

L, nontumorous liver parenchyme x 1

A1-2, tumor and adjacent adrenal gland x 2

B1-2, liver parenchyma x 2

GB, gallbladder x 1

MICROSCOPIC:

Tumor type: Hepatocellular carcinoma

Edmondson-steiner grade

The worst differentiation IV

The major differentiation III

Histologic type: Cord-like and nesting

Fatty change: No

Fibrous capsule formation: Yes

Capsular infiltration: Yes, focal

[page 2 of 2]
Septum formation: Yes
Surgical resection margin invasion: No
Serosal invasion: No
Portal vein invasion: Not identified
Vascular invasion: No
Bile duct invasion: No
Remaining liver parenchyme: Chronic hepatitis, HBV associated

NOT reported. Gross:

liver,ectomy,Hepatocellular carcinoma
T56000, P10, M81703
adrenal gland,ectomy,no tumor
T93000, P10, M09450
gallbladder,ectomy,autolysis
T57000, P10, M54001

DIAGNOSIS:

Liver, right posterior, sectionectomy:
Hepatocellular carcinoma

Adrenal gland, right, adrenalectomy:
No tumor present

Gallbladder, cholecystectomy:
Autolysis

Suggestion :

Source: NCI Genomic Data Commons file 5e02e5d1-a064-4f6a-855e-063c967151e2 (TCGA-DD-AADD.DCDE4D46-AB4E-4C21-9F01-35A304FFF8D5.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).